Somatic mutation profile of tumor specimen MP2PRT-PASDGZ-TMP1-A (aliquot MP2PRT-PASDGZ-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASDGZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,263 days).
Specimen MP2PRT-PASDGZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e1a7086-b107-4d7a-a646-266b317a5ecf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASDGZ-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASDGZ-NB1-B-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3153ac3-6c01-4d93-871c-536615eee02c

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 38/381 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs121913236, CM070964, COSV55526911, COSV55779357; ClinVar: likely pathogenic; called by muse, mutect2
- NSD2 | c.3374A>G p.D1125G | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56397674; called by muse, mutect2, varscan2
- PDE3A | c.2975G>A p.R992H | Missense Mutation (SNP) | VAF 174/364 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100763041; called by muse, mutect2, varscan2
- PDHA2 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 183/357 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV54779547; called by muse, mutect2, varscan2
- RYR2 | c.4499G>A p.R1500H | Missense Mutation (SNP) | VAF 178/353 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs749719028, COSV63657232; called by muse, mutect2, varscan2
- CEP128 | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CHGB | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 39/387 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.022); called by muse, mutect2
- EXOC3L4 | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 151/378 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MSH5 | c.246_247insCCCCT p.E83Pfs*30 | Frame Shift Ins (INS) | VAF 100/256 reads (39%) | called by mutect2, varscan2
- TFPI | c.489C>A p.N163K | Missense Mutation (SNP) | VAF 20/446 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL14A1 | c.2514C>G p.S838= | Silent (SNP) | VAF 108/295 reads (37%) | called by muse, mutect2, varscan2
- EZHIP | c.624G>A p.E208= | Silent (SNP) | VAF 30/667 reads (4%) | called by muse, mutect2
- IQCA1L | c.2151G>A p.P717= | Silent (SNP) | VAF 17/404 reads (4%) | catalogued as rs1379287456; called by muse, mutect2
- KIF19 | c.1017C>T p.Y339= | Silent (SNP) | VAF 24/297 reads (8%) | catalogued as rs376195077; called by muse, mutect2
- MAFB | c.39C>T p.T13= | Silent (SNP) | VAF 117/354 reads (33%) | catalogued as rs1314916717; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849140 C>T | 5'Flank (SNP) | VAF 24/297 reads (8%) | catalogued as rs753367647; called by muse, mutect2
